Somatic mutation profile of tumor specimen TCGA-RQ-AAAT-01A (aliquot TCGA-RQ-AAAT-01A-11D-A38X-10) from TCGA case TCGA-RQ-AAAT, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Primary diffuse large B-cell lymphoma of the CNS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 63.5 years (23,178 days).
Specimen TCGA-RQ-AAAT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8388869-433b-4b0d-af6d-b06cbe032cff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RQ-AAAT-10A (Blood Derived Normal), aliquot TCGA-RQ-AAAT-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f75e14f4-fb2d-429b-a767-7972f10146d7

The open-access MAF lists 177 somatic variants for this specimen: 130 protein-altering or splice-affecting, 44 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 44, Splice Site 7, Splice Region 3, Frame Shift Ins 3, 3'Flank 2, Frame Shift Del 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD7 | c.2413dup p.I805Nfs*20 | Frame Shift Ins (INS) | VAF 31/154 reads (20%) | catalogued as rs1554593023; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIM1 | c.72G>C p.K24N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.48); PolyPhen benign (0.062); catalogued as COSV65164988, COSV65166078, COSV65166386; called by muse, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 28/42 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCG4 | c.1819C>T p.R607* | Nonsense Mutation (SNP) | VAF 41/160 reads (26%) | catalogued as rs745702387, COSV100266573; called by muse, mutect2, varscan2
- ADAMTS18 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1165807118, COSV51399476, COSV99271526; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1341G>A p.P447= | Splice Region (SNP) | VAF 16/45 reads (36%) | catalogued as rs778333493, COSV99441356; called by muse, mutect2, varscan2
- AKAP4 | c.2234G>C p.G745A | Missense Mutation (SNP) | VAF 91/124 reads (73%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100654181; called by muse, mutect2, varscan2
- ALDH8A1 | c.1351A>T p.R451W | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99664501; called by muse, mutect2, varscan2
- APMAP | c.213-1G>A p.X71_splice | Splice Site (SNP) | VAF 20/42 reads (48%) | catalogued as COSV99468268; called by muse, mutect2, varscan2
- ARHGEF10 | c.238G>A p.G80R (on ENST00000398564; = p.G56R on NM_014629.4) | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.035); catalogued as COSV100034048; called by muse, mutect2, varscan2
- BCL11A | c.1909G>A p.D637N (on ENST00000335712 / NM_001365609.1; = p.D671N on NM_018014.4) | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.328); catalogued as COSV100185021; called by muse, mutect2
- BMPER | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.535); catalogued as rs1412919608, COSV99779087; called by muse, mutect2, varscan2
- BNC2 | c.329A>T p.Q110L | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV101032400, COSV66158671; called by muse, mutect2, varscan2
- BTG2 | c.93C>G p.S31R | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.144); catalogued as COSV99305624; called by muse, varscan2
- BTG2 | c.97C>A p.Q33K | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT tolerated (0.52); PolyPhen benign (0.1); catalogued as COSV99305626; called by muse, varscan2
- BTG2 | c.133G>C p.A45P | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.988); catalogued as COSV51856494, COSV99305486; called by muse, varscan2
- C1S | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.9); PolyPhen benign (0.01); catalogued as rs147341600; called by muse, mutect2, varscan2
- CACNA1H | c.2584G>A p.G862S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.636); catalogued as rs747426357, COSV100673442, COSV61991324; called by muse, mutect2, varscan2
- CACNA2D3 | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs762550479, COSV99871175; called by muse, mutect2, varscan2
- CD79B | c.587A>T p.Y196F | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV50076054, COSV50076156, COSV50076492; called by muse, mutect2, varscan2
- CEP112 | c.565-1G>T p.X189_splice | Splice Site (SNP) | VAF 131/274 reads (48%) | catalogued as COSV67138379; called by muse, mutect2, varscan2
- CGN | c.3274G>A p.E1092K | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777033774, COSV99642002; called by muse, mutect2, varscan2
- CHMP2B | c.278A>G p.N93S | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV99773239; called by muse, mutect2, varscan2
- CILP2 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.946); catalogued as rs1442948935, COSV99364407; called by muse, mutect2, varscan2
- CRYBG1 | c.3886T>G p.L1296V | Missense Mutation (SNP) | VAF 56/64 reads (88%) | SIFT tolerated (0.42); PolyPhen benign (0.098); catalogued as COSV100954413; called by muse, mutect2, varscan2
- DDR2 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1340393535, COSV100906242, COSV63371908; called by muse, mutect2, varscan2
- DGKK | c.2731C>A p.L911M | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101052906; called by muse, mutect2, varscan2
- DLG2 | c.435G>A p.R145= | Splice Region (SNP) | VAF 19/80 reads (24%) | catalogued as rs1182048027, COSV99713176, COSV99717064; called by muse, mutect2, varscan2
- DLGAP2 | c.495C>A p.H165Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV101421261; called by muse, mutect2, varscan2
- DNAH17 | c.7469C>T p.S2490L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101101642; called by muse, mutect2
- DYNC2H1 | c.9082G>A p.D3028N | Missense Mutation (SNP) | VAF 97/181 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100517790; called by muse, mutect2, varscan2
- EIF3B | c.1404-2A>C p.X468_splice | Splice Site (SNP) | VAF 119/339 reads (35%) | catalogued as COSV100703580; called by muse, mutect2, varscan2
- ERBB4 | c.839A>C p.N280T | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as COSV53526905, COSV99618152; called by muse, mutect2, varscan2
- ETAA1 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs777386751, COSV99712614; called by muse, mutect2
- ETFDH | c.37T>G p.Y13D | Missense Mutation (SNP) | VAF 202/329 reads (61%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.006); catalogued as COSV100309800; called by muse, mutect2, varscan2
- FAM13A | c.844-1G>T p.X282_splice | Splice Site (SNP) | VAF 18/67 reads (27%) | catalogued as rs766650663, COSV99983013; called by muse, mutect2, varscan2
- FAM181B | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV61300360, COSV61300480; called by muse, mutect2, varscan2
- FAM189B | c.1126C>T p.L376F | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as COSV100617333; called by muse, mutect2, varscan2
- FOXC1 | c.229G>T p.V77L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs765987336, COSV101083238, COSV101083394; called by muse, mutect2, varscan2
- FZD1 | c.755A>G p.Q252R | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99842404; called by muse, mutect2, varscan2
- GBX2 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as COSV100103449; called by muse, mutect2, varscan2
- GCNT1 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100946477; called by muse, mutect2, varscan2
- GML | c.208T>C p.Y70H | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV99638133; called by muse, mutect2, varscan2
- GRID1 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs752715356, COSV100022404, COSV60016469, COSV60056647; called by muse, mutect2, varscan2
- GUF1 | c.148A>G p.S50G | Missense Mutation (SNP) | VAF 33/223 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99877092; called by muse, mutect2, varscan2
- H1-2 | c.327G>C p.K109N | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59190495, COSV59190892; called by muse, mutect2, varscan2
- H2BC21 | c.319C>G p.L107V | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); catalogued as rs587684290, COSV58612872; called by muse, mutect2, varscan2
- HLA-DPA1 | c.35C>G p.A12G | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV101330979; called by muse, mutect2, varscan2
- HLA-DPA1 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as rs867613888, COSV101330980; called by muse, mutect2, varscan2
- HMCN1 | c.5771C>G p.A1924G | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs1371853709, COSV99625281; called by muse, mutect2, varscan2
- IFRD1 | c.783G>T p.K261N | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.058); catalogued as COSV99133672; called by muse, mutect2, varscan2
- IGHM | c.1358C>T p.T453I | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs374309930; called by muse, mutect2, varscan2
- IGHV3-72 | c.220G>C p.A74P | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.042); catalogued as rs777687277, COSV101455362; called by muse, varscan2
- IGHV3-72 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.236); catalogued as rs548318617, COSV101455363; called by muse, varscan2
- IGKV1D-43 | c.112G>C p.G38R | Missense Mutation (SNP) | VAF 82/190 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as rs548069851; called by muse, varscan2
- IGLC3 | c.90A>G p.I30M | Missense Mutation (SNP) | VAF 74/224 reads (33%) | PolyPhen possibly damaging (0.543); catalogued as rs765460732; called by muse, varscan2
- IGLV4-60 | c.228C>G p.S76R | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as rs372802349; called by muse, mutect2, varscan2
- IGSF11 | c.101T>C p.V34A (on ENST00000393775 / NM_001015887.3; = p.V33A on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100677108; called by muse, mutect2, varscan2
- IPO7 | c.2473G>A p.V825I | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV101121790; called by muse, mutect2, varscan2
- KCND2 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100474139, COSV58584879; called by muse, mutect2, varscan2
- KIRREL3 | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as rs755403705, COSV101375175; called by muse, mutect2, varscan2
- LAMB1 | c.1843C>T p.R615C | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs1436222151, COSV55961211; called by muse, mutect2, varscan2
- LGALS13 | c.106C>A p.L36M | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.922); catalogued as rs769612129, COSV99694888; called by muse, mutect2, varscan2
- LRP2 | c.7919T>C p.I2640T | Missense Mutation (SNP) | VAF 80/142 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV99786902; called by muse, mutect2, varscan2
- LTB | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV100272147, COSV59864787; called by muse, mutect2, varscan2
- LZTS2 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs1189867763, COSV64653000; called by muse, mutect2, varscan2
- MAGI1 | c.1586G>A p.G529E | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100439688; called by muse, mutect2, varscan2
- MAN2B2 | c.2409G>C p.W803C | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99577061; called by muse, mutect2, varscan2
- MAP1B | c.3181C>A p.Q1061K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99701937; called by muse, mutect2, varscan2
- MAP1S | c.2614C>T p.R872C | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.365); catalogued as rs762734455, COSV100140895; called by muse, mutect2, varscan2
- MAST1 | c.3702C>A p.S1234R | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); catalogued as COSV99262468; called by muse, mutect2, varscan2
- MCC | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.099); catalogued as rs373730711; called by muse, mutect2, varscan2
- MCOLN1 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as rs765405116, COSV99900421; called by muse, mutect2, varscan2
- MFSD6 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 61/96 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as rs913751558, COSV55621533; called by muse, mutect2, varscan2
- MIA | c.283G>C p.D95H | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV99648165; called by muse, mutect2, varscan2
- NAV3 | c.1040T>A p.M347K | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99887780; called by muse, mutect2, varscan2
- NFATC1 | c.77C>G p.T26S | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.001); catalogued as COSV53700832; called by muse, mutect2, varscan2
- NPEPL1 | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.374); catalogued as COSV100622350; called by muse, mutect2, varscan2
- NUP214 | c.4133dup p.V1379Gfs*60 | Frame Shift Ins (INS) | VAF 25/74 reads (34%) | catalogued as rs780417788; called by mutect2, varscan2
- OR51I2 | c.634T>C p.F212L | Missense Mutation (SNP) | VAF 50/322 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100413321; called by muse, mutect2, varscan2
- OR52R1 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs758370052, COSV61888958; called by muse, mutect2, varscan2
- OR6N1 | c.737C>T p.T246I | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.038); catalogued as COSV100625102; called by muse, mutect2
- OR8K5 | c.709G>C p.A237P | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as COSV57888808, COSV57889280, COSV57889510; called by muse, mutect2, varscan2
- OTULIN | c.383A>T p.Y128F | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV99419605; called by muse, mutect2, varscan2
- PABPC1 | c.280C>G p.R94G | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV100589392, COSV59400103; called by muse, mutect2, varscan2
- PCARE | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.183); catalogued as COSV100527378; called by muse, mutect2, varscan2
- PDLIM5 | c.1464+1G>A p.X488_splice | Splice Site (SNP) | VAF 42/189 reads (22%) | catalogued as COSV100523403; called by muse, mutect2, varscan2
- PER1 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as rs769946260, COSV100424324; called by muse, mutect2, varscan2
- PIM1 | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV65166500, COSV65166793; called by muse, varscan2
- PIM1 | c.543G>C p.E181D | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV100998705, COSV65165102; called by muse, mutect2, varscan2
- PLCH2 | c.1583C>T p.S528L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs755572589, COSV99615687; called by muse, mutect2, varscan2
- PLEKHA1 | c.761G>C p.R254T | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100935444, COSV100935604; called by muse, mutect2, varscan2
- PRDM15 | c.1489T>C p.Y497H | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.942); catalogued as COSV99519493; called by muse, mutect2, varscan2
- PUS1 | c.1115A>G p.H372R | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV100435148; called by muse, mutect2, varscan2
- RAB22A | c.320G>A p.G107D | Missense Mutation (SNP) | VAF 80/195 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99720010; called by muse, mutect2, varscan2
- RABGAP1 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1406651297, COSV58061449; called by muse, mutect2, varscan2
- RFX5 | c.107G>A p.G36D | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs764561345, COSV100923836; called by muse, mutect2, varscan2
- RPL13 | c.302G>A p.R101K | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1366482540, COSV99244672; called by muse, mutect2, varscan2
- RPTN | c.602G>T p.S201I | Missense Mutation (SNP) | VAF 121/261 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV100285306; called by muse, mutect2, varscan2
- RPUSD4 | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); catalogued as COSV100028616; called by muse, mutect2, varscan2
- SACS | c.4852T>C p.F1618L | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV101207229; called by muse, mutect2, varscan2
- SCNN1A | c.1760G>A p.R587K | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV99964467, COSV99964554; called by muse, mutect2, varscan2
- SLC1A6 | c.684C>A p.F228L | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99693475; called by muse, mutect2, varscan2
- SON | c.1010T>C p.L337P | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.925); catalogued as COSV99277169; called by muse, mutect2, varscan2
- SOX7 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs768027133, COSV100448980, COSV100449205; called by muse, mutect2, varscan2
- SPATA20 | c.1942G>A p.V648M (on ENST00000356488 / NM_001258372.1; = p.V664M on NM_022827.4) | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs200274697, COSV99135596; called by muse, mutect2, varscan2
- SPATA31D1 | c.3938C>T p.T1313I | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV100782547; called by muse, mutect2, varscan2
- SRPRA | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781751244, COSV55006219; called by muse, mutect2, varscan2
- STAT3 | c.1847A>G p.E616G | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV52883602; called by muse, mutect2, varscan2
- STAT4 | c.1254C>A p.G418= | Splice Region (SNP) | VAF 32/151 reads (21%) | catalogued as COSV61828273; called by muse, mutect2, varscan2
- TBX19 | c.1087G>T p.A363S | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100892335; called by muse, mutect2
- TENM3 | c.2527T>G p.F843V | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV101304932; called by muse, mutect2, varscan2
- TGFBR3 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as rs751917590, COSV53032978; called by muse, mutect2, varscan2
- TRIM72 | c.548T>C p.L183P | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100265361; called by muse, mutect2, varscan2
- TRPM2 | c.441G>T p.Q147H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV100308316; called by muse, mutect2
- TRPM7 | c.2384C>A p.T795K | Missense Mutation (SNP) | VAF 76/408 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.054); catalogued as COSV100539486; called by muse, mutect2, varscan2
- TSPAN12 | c.592C>G p.L198V | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as COSV99763053; called by mutect2, varscan2
- UBE2A | c.331-2A>C p.X111_splice | Splice Site (SNP) | VAF 33/41 reads (80%) | catalogued as COSV100660485; called by muse, mutect2, varscan2
- VANGL1 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199932833, COSV100048908; called by muse, mutect2, varscan2
- VPS13C | c.3321C>G p.I1107M (on ENST00000644861 / NM_020821.3; = p.I1064M on NM_017684.5) | Missense Mutation (SNP) | VAF 120/140 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99827545; called by muse, mutect2, varscan2
- ZNF552 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 65/277 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs576029108, COSV66971575; called by muse, mutect2, varscan2
- ZNRF4 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as rs375118147; called by muse, mutect2, varscan2
- IGHM | c.300C>G p.N100K | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.84); called by muse, mutect2, varscan2
- IGHM | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (1); called by muse, mutect2
- IGHM | c.61A>T p.T21S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.42); called by muse, mutect2, varscan2
- IGLV5-52 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- ITPKB | c.301_304del p.S101Gfs*42 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel, varscan2
- RASAL1 | c.341dup p.E115Rfs*5 | Frame Shift Ins (INS) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- SPTBN4 | c.6957-4_6988del p.X2319_splice | Splice Site (DEL) | VAF 5/32 reads (16%) | called by mutect2, pindel
- TPTE | c.504T>G p.I168M (on ENST00000618007 / NM_199261.4; = p.I150M on NM_199259.4) | Missense Mutation (SNP) | VAF 45/337 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- ADGRE5 | c.1134C>T p.S378= (on ENST00000242786 / NM_078481.4; = p.S285= on NM_001784.5) | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as rs756516696, COSV99662689; called by muse, mutect2
- BTG1 | c.109C>T p.L37= | Silent (SNP) | VAF 58/128 reads (45%) | catalogued as rs369374957, COSV55458204, COSV55458724; called by muse, mutect2, varscan2
- CSMD1 | c.2454G>C p.G818= (on ENST00000520002; = p.G817= on NM_033225.6) | Silent (SNP) | VAF 37/90 reads (41%) | called by muse, mutect2, varscan2
- CTSC | c.84C>T p.A28= | Silent (SNP) | VAF 21/177 reads (12%) | catalogued as COSV99910535; called by muse, mutect2, varscan2
- DKK2 | c.444A>G p.R148= | Silent (SNP) | VAF 142/209 reads (68%) | catalogued as COSV99568277; called by muse, mutect2, varscan2
- DNASE1L2 | c.645G>A p.Q215= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV100065455; called by muse, mutect2, varscan2
- DTX1 | c.27G>C p.L9= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV99986235; called by muse, varscan2
- DTX1 | c.204G>A p.Q68= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV104379963, COSV57502295; called by muse, varscan2
- ENPP2 | c.474T>A p.P158= | Silent (SNP) | VAF 50/112 reads (45%) | catalogued as COSV99307716; called by muse, mutect2, varscan2
- FAM171A1 | c.1974T>C p.P658= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV100968108; called by muse, mutect2, varscan2
- FGG | c.1239C>A p.I413= | Silent (SNP) | VAF 33/158 reads (21%) | catalogued as COSV100271737, COSV100271937; called by muse, mutect2, varscan2
- GRIA2 | c.108C>T p.G36= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV52385756; called by muse, mutect2, varscan2
- H1-4 | c.282G>A p.V94= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as rs549787183, COSV99175207; called by muse, varscan2
- H1-4 | c.351G>A p.K117= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as rs376044340, COSV56799955; called by muse, varscan2
- H2BC5 | c.129C>T p.Y43= | Silent (SNP) | VAF 19/113 reads (17%) | catalogued as COSV56800984, COSV99175227; called by muse, mutect2, varscan2
- IGHG1 | c.225C>T p.S75= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs767185975; called by muse, mutect2, varscan2
- IGHM | c.324G>A p.E108= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as rs1161329191; called by muse, varscan2
- IGHM | c.156C>T p.S52= | Silent (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2
- IGKV1D-43 | c.321T>C p.T107= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as rs1558646073; called by muse, mutect2, varscan2
- IGLV5-52 | c.291A>T p.A97= | Silent (SNP) | VAF 20/31 reads (65%) | called by muse, mutect2, varscan2
- IGLV6-57 | c.318T>A p.A106= | Silent (SNP) | VAF 24/29 reads (83%) | catalogued as COSV101135299; called by muse, mutect2, varscan2
- ITPKB | c.57G>A p.E19= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV55256741, COSV99683863; called by muse, mutect2, varscan2
- KIF6 | c.336G>A p.E112= | Silent (SNP) | VAF 46/121 reads (38%) | catalogued as rs1016388583, COSV99757668; called by muse, mutect2, varscan2
- LCA5 | c.390A>C p.L130= | Silent (SNP) | VAF 110/160 reads (69%) | catalogued as COSV100878184; called by muse, mutect2, varscan2
- LMNB1 | c.330C>T p.C110= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs1351184689, COSV99745668; called by muse, mutect2
- LRRIQ1 | c.2493T>G p.T831= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV101279666; called by muse, mutect2, varscan2
- MACC1 | c.963A>G p.K321= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as COSV100255520; called by muse, mutect2, varscan2
- NGLY1 | c.855C>T p.A285= | Silent (SNP) | VAF 14/156 reads (9%) | catalogued as COSV99770181; called by muse, mutect2
- NPAS1 | c.171G>C p.R57= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV101496862; called by muse, mutect2
- NPEPL1 | c.468G>A p.V156= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV100622348; called by muse, mutect2, varscan2
- PCDHA4 | c.84C>T p.N28= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as COSV63540370; called by muse, mutect2, varscan2
- PCDHB5 | c.2052G>A p.S684= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs782577953, COSV50669731; called by muse, mutect2, varscan2
- PIM1 | c.51C>T p.C17= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs1485392438, COSV100998611; called by muse, varscan2
- PKHD1 | c.11034T>C p.I3678= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV100943844; called by muse, mutect2, varscan2
- PLXNA3 | c.1650A>C p.S550= | Silent (SNP) | VAF 54/187 reads (29%) | catalogued as COSV100859830; called by muse, mutect2, varscan2
- PMF1 | c.96T>C p.I32= | Silent (SNP) | VAF 40/90 reads (44%) | catalogued as COSV100195794; called by muse, mutect2, varscan2
- PNKP | c.807G>A p.L269= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV99681600; called by muse, mutect2, varscan2
- POU3F3 | c.1260G>A p.A420= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as COSV100796840, COSV63721329; called by muse, mutect2, varscan2
- REPS1 | c.1099T>C p.L367= | Silent (SNP) | VAF 48/66 reads (73%) | catalogued as COSV99238475; called by muse, mutect2, varscan2
- SEC24B | c.507T>C p.S169= | Silent (SNP) | VAF 37/178 reads (21%) | catalogued as COSV99493036; called by muse, mutect2, varscan2
- SLITRK1 | c.1218G>T p.L406= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as COSV100999825; called by muse, mutect2, varscan2
- TCTN2 | c.477C>T p.V159= | Silent (SNP) | VAF 79/235 reads (34%) | catalogued as rs1294551315, COSV100315114; called by muse, varscan2
- TEX13A | c.339G>A p.K113= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV100780814; called by muse, mutect2, varscan2
- WASL | c.48C>T p.N16= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV99771527; called by muse, mutect2, varscan2
- IGLL5 | chr22:22901083 G>A | 3'Flank (SNP) | VAF 79/137 reads (58%) | called by muse, varscan2
- KCNIP4 | c.61+251168T>A | Intron (SNP) | VAF 46/76 reads (61%) | catalogued as COSV101184753; called by muse, varscan2
- ROR2 | chr9:91722533 C>T | 3'Flank (SNP) | VAF 32/82 reads (39%) | catalogued as rs1303750881, COSV100995400, COSV100995575; called by muse, mutect2, varscan2
